Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7416, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7416-01A (Primary Tumor).

SUPPLEMENTAL REPORT

COMMENT: Sections of the mandibular condyle which has been decalcified show squamous carcinoma destroying the mandibular ramus and infiltrating through the articular surface of the condyle into the temporal mandibular joint.

DIAGNOSIS

(A) LEFT MAXILLECTOMY, MANDIBULECTOMY, BILATERAL NECK DISSECTION, TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND INFRATEMPORAL RESECTION:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED,
19.0 X 12.0 X 6.0 CM. (SEE COMMENT)

(B) TEETH:

Five molar teeth.

COMMENT

Squamous carcinoma infiltrates the temporomandibular joint, mandibular ramus, palate, oropharynx, tongue, laryngeal cartilage and soft tissue of the neck bilaterally. The mandibular condyle is to be processed following decalcification for which a supplemental report will be issued. Tumor is not present in the representative margins examined.

SPECIMEN

(A) LEFT MAXILLECTOMY, MANDIBULECTOMY, BILATERAL NECK DISSECTION, TOTAL

(B) TEETH:

SNOMED CODES

T-51004,M-80703

Source: NCI Genomic Data Commons file 571dcf71-7bd6-432c-a7c7-3ebf1b82e910 (TCGA-CV-7416.BD433DE1-6596-4405-98B3-DD7DBC51F202.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).